Somatic mutation profile of tumor specimen TCGA-J2-A4AE-01A (aliquot TCGA-J2-A4AE-01A-21D-A24D-08) from TCGA case TCGA-J2-A4AE, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 77.1 years (28,163 days).
Specimen TCGA-J2-A4AE-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 781eaeea-7011-4738-84ec-da4e8534af1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J2-A4AE-10A (Blood Derived Normal), aliquot TCGA-J2-A4AE-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/07d5681a-c07b-4a25-bfc3-c8b56e36445c

The open-access MAF lists 59 somatic variants for this specimen: 38 protein-altering or splice-affecting, 17 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, Silent 17, Frame Shift Del 3, 5'UTR 2, Intron 1, RNA 1, Splice Site 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABI3 | c.991G>A p.E331K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV56800028; called by muse, mutect2, varscan2
- AFAP1L2 | c.2390T>C p.V797A (on ENST00000304129 / NM_001351075.1; = p.V793A on NM_032550.3 and 11 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.25); PolyPhen benign (0.398); catalogued as COSV100412841; called by muse, mutect2, varscan2
- ARMCX2 | c.131G>A p.R44Q | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.018); catalogued as rs370150016, COSV100168236; called by muse, mutect2, varscan2
- BNC2 | c.2689G>T p.D897Y | Missense Mutation (SNP) | VAF 18/83 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.894); catalogued as COSV101035740, COSV101036684; called by muse, mutect2, varscan2
- COL6A3 | c.8477T>A p.F2826Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as COSV99800181; called by muse, mutect2
- DMBT1 | c.5420G>A p.C1807Y (on ENST00000338354 / NM_001377530.1; = p.C1050Y on NM_004406.3) | Missense Mutation (SNP) | VAF 18/256 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100353710; called by muse, mutect2
- EML1 | c.1049A>G p.D350G | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.274); catalogued as COSV99215407; called by muse, mutect2, varscan2
- EPRS1 | c.1393G>A p.G465R | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100859442, COSV65102006; called by muse, mutect2, varscan2
- HMCN1 | c.4661C>A p.T1554N | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99633302; called by muse, mutect2, varscan2
- IFNA10 | c.104G>C p.R35T | Missense Mutation (SNP) | VAF 28/142 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.109); catalogued as COSV99497555; called by muse, mutect2, varscan2
- IFNA5 | c.394A>G p.T132A | Missense Mutation (SNP) | VAF 59/232 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.012); catalogued as COSV99423735; called by muse, mutect2, varscan2
- INSC | c.58C>G p.L20V | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as COSV101089491, COSV65410408; called by muse, mutect2, varscan2
- LAMA5 | c.2182G>T p.A728S | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.836); catalogued as COSV99441399; called by muse, mutect2, varscan2
- LAMP5 | c.235G>A p.D79N | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1171815695, COSV99855657; called by muse, mutect2, varscan2
- MANBA | c.2759C>A p.S920Y (on ENST00000642252; = p.S874Y on NM_005908.4) | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99899016; called by muse, mutect2
- MEGF8 | c.4073C>T p.S1358L (on ENST00000251268 / NM_001271938.2; = p.S1291L on NM_001410.3) | Missense Mutation (SNP) | VAF 20/200 reads (10%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs760451604, COSV99238130; called by muse, mutect2
- MET | c.3028+1del | Frame Shift Del (DEL) | VAF 12/37 reads (32%) | catalogued as COSV59259218, COSV59259530, COSV59268643; called by mutect2, pindel, varscan2
- MMP10 | c.386T>C p.V129A | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.799); catalogued as COSV99666689; called by muse, mutect2
- NAV3 | c.4334G>A p.R1445H | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.998); catalogued as rs768831417, COSV99893890; called by muse, mutect2
- NUP155 | c.257G>A p.R86K (on ENST00000231498 / NM_153485.3; = p.R27K on NM_004298.4) | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.177); catalogued as COSV99193996; called by muse, mutect2, varscan2
- OR5B17 | c.358C>T p.R120C | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.155); catalogued as rs142474037; called by muse, mutect2, varscan2
- PLVAP | c.700G>C p.E234Q | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT tolerated (0.24); PolyPhen benign (0.054); catalogued as COSV99391637, COSV99391774; called by muse, mutect2
- RAD52 | c.1101G>C p.Q367H | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.438); catalogued as rs766789173, COSV99942644; called by muse, mutect2, varscan2
- RNF165 | c.674G>A p.G225E | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.206); catalogued as COSV53975829; called by muse, mutect2
- SCN4A | c.472A>C p.K158Q | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.268); catalogued as COSV101438591; called by muse, mutect2
- SUPT20H | c.166-1G>C p.X56_splice (on ENST00000350612 / NM_001014286.3; = p.Q56H on NM_017569.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 4/33 reads (12%) | catalogued as COSV100634775; called by muse, mutect2, varscan2
- THPO | c.1364C>T p.T455I (on ENST00000649095 / NM_001290003.1; = p.T315I on NM_000460.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/103 reads (12%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as rs562029329, COSV52617673; called by muse, mutect2, varscan2
- TOGARAM1 | c.1555C>G p.L519V | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753984118, COSV61888259; called by muse, mutect2, varscan2
- TRDV1 | c.333T>A p.C111* | Nonsense Mutation (SNP) | VAF 3/38 reads (8%) | catalogued as COSV101153562; called by muse, mutect2
- VPS9D1 | c.1355C>G p.S452C | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.635); catalogued as COSV101232024; called by muse, mutect2
- XYLT1 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 27/137 reads (20%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs142548093; called by muse, mutect2, varscan2
- ZIM2 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 30/92 reads (33%) | SIFT tolerated (0.87); PolyPhen benign (0.012); catalogued as rs149106731; called by muse, mutect2, varscan2
- ZNF208 | c.590G>C p.R197T | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.615); catalogued as COSV101237163; called by muse, mutect2, varscan2
- ZNF474 | c.761T>C p.L254P | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs761180146, COSV99682247; called by muse, mutect2, varscan2
- MCM7 | c.1395G>C p.Q465H | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RB1 | c.442_443del p.M148Vfs*8 | Frame Shift Del (DEL) | VAF 10/46 reads (22%) | called by mutect2, pindel, varscan2
- RB1 | c.711del p.E237Dfs*27 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel
- ZNF608 | c.1831G>A p.E611K | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.921); called by muse, mutect2
- ATN1 | c.363T>C p.P121= | Silent (SNP) | VAF 6/56 reads (11%) | catalogued as rs1555143454, COSV100755898; called by muse, mutect2
- CD274 | c.168T>C p.Y56= | Silent (SNP) | VAF 13/52 reads (25%) | catalogued as COSV101056092; called by muse, mutect2, varscan2
- CDC42BPB | c.4296C>T p.L1432= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as COSV100775554; called by muse, mutect2, varscan2
- CES2 | c.933C>T p.P311= | Silent (SNP) | VAF 19/71 reads (27%) | catalogued as rs755907689, COSV100399359; called by muse, mutect2, varscan2
- DIPK1C | c.963C>T p.C321= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV100679933; called by muse, mutect2, varscan2
- FRYL | c.1807C>T p.L603= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs747517529, COSV99977653; called by muse, mutect2, varscan2
- GNAS | c.252C>T p.S84= | Silent (SNP) | VAF 16/96 reads (17%) | catalogued as rs1395630112, COSV99670679; called by mutect2, varscan2
- HOXB7 | c.489G>A p.T163= | Silent (SNP) | VAF 18/71 reads (25%) | catalogued as rs897428031, COSV53310705, COSV53311841; called by muse, mutect2, varscan2
- LIPI | c.447C>T p.N149= | Silent (SNP) | VAF 8/31 reads (26%) | catalogued as COSV100753893; called by muse, mutect2, varscan2
- MTHFD1L | c.1791C>T p.G597= | Silent (SNP) | VAF 7/69 reads (10%) | catalogued as COSV100945245; called by muse, mutect2
- OR2J2 | c.120G>A p.L40= | Silent (SNP) | VAF 20/232 reads (9%) | catalogued as COSV65847742; called by muse, mutect2
- PCDH17 | c.2049G>A p.S683= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as rs972459527, COSV64974519; called by muse, mutect2, varscan2
- SLC16A5 | c.285G>A p.V95= | Silent (SNP) | VAF 6/128 reads (5%) | called by muse, mutect2
- SUSD1 | c.816C>T p.S272= | Silent (SNP) | VAF 37/119 reads (31%) | catalogued as COSV100813438; called by muse, mutect2, varscan2
- TTN | c.37692G>A p.L12564= (on ENST00000591111; = p.L5140= on NM_003319.4) | Silent (SNP) | VAF 14/204 reads (7%) | catalogued as COSV100623142; called by muse, mutect2
- UBTF | c.513G>A p.E171= | Silent (SNP) | VAF 4/57 reads (7%) | called by muse, mutect2
- VCX | c.261C>T p.H87= | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as rs377239917, COSV100406349; called by muse, mutect2, varscan2
- AL163540.1 | n.53C>T | RNA (SNP) | VAF 10/120 reads (8%) | called by muse, mutect2, varscan2
- GORAB | c.-16C>T | 5'UTR (SNP) | VAF 4/54 reads (7%) | catalogued as COSV100883774; called by muse, mutect2
- PCDHA2 | c.2388+23C>A | Intron (SNP) | VAF 7/41 reads (17%) | catalogued as COSV100974080; called by muse, mutect2
- SWI5 | c.-117G>C | 5'UTR (SNP) | VAF 5/46 reads (11%) | catalogued as COSV100199732, COSV60792234; called by muse, mutect2
